MMRF case MMRF_2150 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0f98b1a9-13d4-41be-87dd-20f6bb76de52

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,157 days); Days to last known disease status: 905 days (2.5 years); Days to last follow up: 905 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.523 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.1 mg/dL; Immunoglobulin G 2.11 g/L; Immunoglobulin A 44.7 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.09 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 8.2 g/dL; Glucose 6 mmol/L.
- Day 83: Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.91 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 161 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.775 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.38 mg/dL; Immunoglobulin G 2.45 g/L; Immunoglobulin A 10.7 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 7.26 mmol/L.
- Day 279 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.52 mg/dL; Immunoglobulin G 2.3 g/L; Immunoglobulin A 14.6 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 5.17 ×10⁹/L; Absolute Neutrophil 3.44 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 363: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.457 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 2.41 g/L; Immunoglobulin A 14.6 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.25 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 452 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.525 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 8.78 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.98 ×10⁹/L; Absolute Neutrophil 2.98 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 533 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.421 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.768 mg/dL; Immunoglobulin G 2.77 g/L; Immunoglobulin A 10.6 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.09 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 628: M Protein 0.6 g/dL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.64 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 5.61 mmol/L.
- Day 701: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.848 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.29 mg/dL; Immunoglobulin G 2.57 g/L; Immunoglobulin A 10.7 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.82 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 4.57 mmol/L.
- Day 792 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.986 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.1 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 15 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.27 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 905: M Protein 1.1 g/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 15.7 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -6: Weight: 74 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2150_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2150_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
